Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A0GQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A0GQ-01A (Primary Tumor).

[page 1 of 2]
ICD - 0 - 3

Adenocarcinoma, Endometrioid NOS

Site: Endometrium c54.1 8380/30 11/27/12

Ordering M.D.:

Age/Sex: _____
Location: _____

Assistant: _____
Date of Procedure: _____
Date Received: _____

3

Copies To:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. LEFT TUBE AND OVARY, SALPINGO-OOPHORECTOMY

- Ovary with no significant pathologic change
- Fallopian tube with paratubal cyst; negative for malignancy

B. RIGHT TUBE AND OVARY, SALPINGO-OOPHORECTOMY

- Ovary with mild cystadenofibromatous changes; negative for malignancy
- Fallopian tube with paratubal cyst; negative for malignancy

C. UTERUS AND CERVIX, HYSTERECTOMY

Cervix

- Negative for malignancy
- Tunnel clusters and lobular endocervical hyperplasia

Endometrium

- Adenocarcinoma of the endometrium, endometrioid type, FIGO grade I of III
- Arising in a background of complex atypical endometrial hyperplasia

Myometrium and serosa

- Endometrioid adenocarcinoma myoinvasive to approximately one-half of myometrium
- No angiolymphatic invasion identified
- Adenomyosis
- Serosa negative for malignancy
- AJCC Pathologic Stage (2002, 6th Ed): pT1c/pN0

D. RIGHT PELVIC LYMPH NODE, EXCISION

- One lymph node negative for malignancy (1)

E. LEFT PELVIC LYMPH NODE, EXCISION

- One lymph node negative for malignancy (1)

HISTORY: Endometrial carcinoma

MICROSCOPIC:

See diagnosis.

GROSS:

A. LEFT TUBE AND OVARY

Labeled with the patient's name, labeled "left tube and ovary", and received in formalin is a salpingo-oophorectomy specimen including a yellow, 1.4 x 0.3 x 0.3 cm ovary and a portion of fimbriated fallopian tube which is 3.0 cm in length x 0.3 cm in diameter. A small 0.4 cm in greatest dimension paratubal cyst is identified. On sectioning no gross lesions are identified. Representative sections are submitted.

Patient Case(s):

Local

[page 2 of 2]
PATH #: [REDACTED]

- A1. Ovary - 2
- A2. Fallopian tube - 3

B. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received in formalin is a salpingo-oophorectomy specimen consisting of a yellow, firm ovary measuring 1.5 x 0.5 x 0.5 cm and a brown fallopian tube measuring 8.0 cm in length x 0.2 cm in diameter. Representative sections are submitted.

- B1. Ovary - 2
- B2. Fallopian tube - 3

C. UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus and cervix", and received in formalin is a 39.6 gram hysterectomy specimen consisting of a previously posteriorly opened uterus. The uterus measures 7.0 x 3.0 x 3.0 cm. The ectocervix measures 1.8 x 0.5 cm. The external os measures 0.4 cm in diameter, and the endocervical canal measures 1.0 cm in length and 0.4 cm in thickness. The endometrial cavity measures 3.0 cm in length x 0.5 cm in width.

The superior 2.3 cm of the endometrial cavity is replaced by a friable, white, exophytic heaped-up mass measuring 2.3 x 2.0 x 1.0 cm. The cut surface reveals invasion of approximately 60% of the depth of the myometrium. The myometrium measures 1.8 cm in thickness. No other gross lesions are identified. Ink key: Anterior surgical margin blue, posterior surgical margin black. Slide key:

- C1. Anterior cervix - 1
- C2. Posterior cervix - 1
- C3. Anterior lower uterine segment - 1
- C4. Posterior lower uterine segment - 1
- C5. Left superior corpus - 1
- C6. Right superior corpus - 1

D. RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "right pelvic lymph node", and received in formalin is a single piece of yellow fatty tissue measuring 2.5 x 1.5 x 0.8 cm. No lymph nodes are grossly identified. The specimen is entirely submitted.

- D1. 1

E. LEFT PELVIC

Labeled with the patient's name, labeled "left pelvic", and received in formalin is a single piece of yellow, lobulated, fatty tissue measuring 2.0 x 1.5 x 0.8 cm. There is one grossly identifiable lymph node measuring 0.8 x 0.4 x 0.2 cm which is submitted.

- E1. 2

Gross dictated by

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

IHPAA Discrepancy		
Local/Regional Recurrence		

Source: NCI Genomic Data Commons file 2d66112d-7852-4087-99a0-c735ab75d54b (TCGA-A5-A0GQ.7B57FD81-AA42-4C76-BF65-0BA2B3451065.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).